Somatic mutation profile of tumor specimen 0DV5SD from CCDI case PBCMAM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 20.4 years (7,435 days).
Specimen 0DV5SD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afc2a1a8-be04-4551-a953-d31d9aed142c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78ef3345-f7da-413d-bbf1-8ce835056f4e

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'Flank 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF142 | c.2393A>G p.Y798C (on ENST00000411696 / NM_001379660.1; = p.Y598C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/139 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1443995865; called by muse, mutect2
- CEP170 | c.3815G>T p.G1272V | Missense Mutation (SNP) | VAF 45/545 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OGDHL | c.21G>T p.L7= | Silent (SNP) | VAF 20/363 reads (6%) | called by muse, mutect2
- ITPRID1 | chr7:31652928 C>A | 3'Flank (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- PHC1 | c.1894-80T>A | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
